Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-A9RM, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-A9RM-01A (Primary Tumor).

SPECIMEN

Bladder tumour

CLINICAL DETAILS

New bladder tumour

? high grade

Part solid part papillary

Adjacent to but not involving RUO

MACROSCOPY

8g of soft friable tissue chippings

MICROSCOPY

Grade:

3 poorly differentiated (there is also a grade 2 papillary component)

Growth pattern:

Mixed papillary and solid

Type:

Transitional cell carcinoma

Muscularis propria:

Present

Stromal invasion:

Invasion of muscularis propria (pT2), (probable, with bulky lamina propria invasion)

Vascular channel invasion:

Not identified

Background urothelium:

Carcinoma in-situ is present in flat urothelium

SUMMARY

Bladder; Transitional Cell Carcinoma G3 pT2

Pathologists -

DR

OBCE
path
ICD-O-3
Carcinoma, urothelial NOS 8120/3
Carcinoma, transitional cell NOS 8120/3
Site: 4 Bladder NOS C67.9
9/2 5/2/14

Source: NCI Genomic Data Commons file 7b27fd41-d361-4840-8897-ffa3787b8d15 (TCGA-ZF-A9RM.F5403E2C-C4B0-4F82-A4E8-E210017FC34B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).